Gene-level copy-number profile of tumor specimen BLGSP-71-19-00522-09A from CGCI case BLGSP-71-19-00522, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 17.3 years (6,310 days).
Specimen BLGSP-71-19-00522-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e1f6f5d7-a410-4e32-832b-2052e43fe09f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-19-00522-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/6dacb65e-2c6f-4554-88b3-3bf2f39453a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 3,140; copy number 2: 55,355; copy number 3: 233; copy number 4: 78; copy number 5: 48.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes (within-gene range 0–2): TTC34, AC242022.2, AC242022.1.
- chr2:89,244,781–89,310,144, 9 genes (within-gene range 0–1): IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr14:105,881,034–106,012,420, 36 genes (within-gene range 0–2): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:88,494,789–93,227,317, 48 genes, copy number 5 (within-gene range 4–5): LINC00433, AL445984.2, LINC00560, GRPEL2P1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.1.

Autosomal genes at a single copy (total copy number 1): 284. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
